Gene-level copy-number profile of tumor specimen TCGA-77-6843-01A from TCGA case TCGA-77-6843, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.7 years (27,291 days).
Specimen TCGA-77-6843-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d7aed2c1-cf7a-4b9f-90a6-3adfbc0e5c26.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-6843-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1fb81c3b-468f-44f3-bc52-02b74dcc5513

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 14,548; copy number 2: 38,537; copy number 3: 5,672; copy number 4: 428; copy number 5: 133; copy number 6: 53; copy number 7: 34; copy number 9: 3; copy number 11: 325; copy number 14: 83.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-6843-01A-11D-1943-01): tumor purity 0.74, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:182,548,659–182,708,042, 3 genes: RNU2-34P, RN7SKP67, AC079226.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 631 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:145,523,538–147,370,656, 19 genes, copy number 6 (within-gene range 3–6): LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1, AC092957.1.
- chr3:147,276,768–148,401,084, 15 genes, copy number 6: RPL21P71, ZIC4, ZIC4-AS1, ZIC1, NPM1P28, AC092925.1, AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046.
- chr3:163,026,396–163,479,500, 5 genes, copy number 5: AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P.
- chr3:167,239,843–191,641,237, 426 genes, copy number 6–14 (broad region; genes not listed).
- chr17:142,789–511,347, 11 genes, copy number 5–14: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2.
- chr17:523,140–553,417, 2 genes, copy number 5: AC015853.3, AC015853.1.
- chr19:17,719,242–19,895,847, 119 genes, copy number 5 (broad region; genes not listed).
- chr19:39,863,323–40,629,818, 34 genes, copy number 7 (within-gene range 3–7): FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4, SHKBP1, LTBP4.

Autosomal genes at a single copy (total copy number 1): 12,161. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
